Somatic mutation profile of tumor specimen C3N-00175-02 (aliquot CPT0013880009) from CPTAC case C3N-00175, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.5 years (26,470 days).
Specimen C3N-00175-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b55379d-89d0-4c02-b81d-6d314c4b7387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00175-31 (Blood Derived Normal), aliquot CPT0016600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b943d6b-ea68-44db-ba33-82264e6a154d

The open-access MAF lists 1,536 somatic variants for this specimen: 1,098 protein-altering or splice-affecting, 285 silent, 153 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 931, Silent 285, Nonsense Mutation 80, Intron 62, Frame Shift Del 38, RNA 36, Splice Site 27, 3'UTR 21, 5'UTR 15, 5'Flank 13, Frame Shift Ins 10, 3'Flank 6.

Variants (750 of 1,536; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.4357+1del p.X1453_splice | Splice Site (DEL) | VAF 19/120 reads (16%) | catalogued as rs397509165, CD057385, CS045208, CS086267, CS119476; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 75/259 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RET | c.1947G>A p.S649= | Silent (SNP) | VAF 59/430 reads (14%) | catalogued as rs377767412, CS962408, COSV60707798; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1532C>T p.P511L (on ENST00000404938 / NM_001163941.2; = p.P66L on NM_178559.6) | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51706031; called by muse, mutect2, varscan2
- ABCD2 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58054568; called by muse, varscan2
- ABHD16A | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776429787; called by muse, mutect2, varscan2
- AC009779.3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs763485368; called by muse, mutect2
- ACE | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 196/483 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1176792351; called by muse, mutect2, varscan2
- ACLY | c.3297G>C p.M1099I | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.138); catalogued as COSV59862201; called by muse, mutect2
- ADAMTS20 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.421); catalogued as COSV101240454; called by muse, mutect2, varscan2
- ADARB1 | c.1685G>T p.R562L (on ENST00000360697 / NM_001346687.2; = p.R522L on NM_001112.4) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100653815; called by muse, mutect2, varscan2
- ADCY2 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770402477, COSV57892241; called by muse, mutect2, varscan2
- ADGRF5 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs199931272, COSV51940547; called by muse, mutect2, varscan2
- ADGRL3 | c.3592-1G>T p.X1198_splice (on ENST00000506720 / NM_001322402.2; = p.X1130_splice on NM_015236.6) | Splice Site (SNP) | VAF 27/120 reads (23%) | catalogued as COSV72229093; called by muse, mutect2, varscan2
- ADRA2C | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1194687074; called by muse, mutect2, varscan2
- AEBP1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757009902, COSV56256190, COSV56260647; called by muse, mutect2, varscan2
- AHNAK | c.16100G>T p.G5367V | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57223295; called by muse, mutect2, varscan2
- AHNAK2 | c.5005G>C p.G1669R | Missense Mutation (SNP) | VAF 264/682 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199554131; called by muse, mutect2, varscan2
- AKAP3 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV57414126; called by muse, mutect2, varscan2
- ALDH2 | c.626A>T p.K209M | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781185157; called by muse, mutect2, varscan2
- ALMS1 | c.8518G>T p.D2840Y | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1157236247, COSV100041083; called by muse, mutect2, varscan2
- AMBRA1 | c.2977-1G>T p.X993_splice (on ENST00000458649 / NM_001367468.1; = p.X903_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV54048471; called by muse, mutect2
- AMER3 | c.2170A>G p.S724G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1167166403; called by muse, mutect2, varscan2
- AMH | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1253721259; called by muse, mutect2, varscan2
- ANAPC5 | c.2137G>T p.V713F | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1479291253, COSV99946339; called by muse, mutect2, varscan2
- ANKRD33B | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV56977155; called by muse, mutect2, varscan2
- ANO7 | c.1299G>A p.W433* (on ENST00000274979; = p.W379* on NM_001370694.2) | Nonsense Mutation (SNP) | VAF 16/190 reads (8%) | catalogued as COSV51470441; called by muse, mutect2
- ANTXR1 | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100362765; called by muse, mutect2, varscan2
- APPL2 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368049760, COSV99315301; called by muse, mutect2, varscan2
- ARHGAP22 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99984640; called by muse, mutect2, varscan2
- ARHGAP25 | c.1130C>T p.A377V (on ENST00000409202 / NM_001007231.3; = p.A369V on NM_014882.3) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1253827900; called by muse, mutect2, varscan2
- ARHGAP32 | c.4063G>T p.D1355Y (on ENST00000310343 / NM_001378025.1; = p.D1006Y on NM_014715.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV100088101; called by muse, mutect2, varscan2
- ARHGAP35 | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101351975, COSV68329650; called by muse, mutect2, varscan2
- ARMH4 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as COSV50772579; called by muse, mutect2, varscan2
- ASCL4 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.132); catalogued as COSV60816943; called by muse, mutect2, varscan2
- ASIC3 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV52506817, COSV99874856; called by muse, mutect2, varscan2
- ASIC4 | c.1046C>T p.P349L (on ENST00000347842 / NM_182847.3; = p.P368L on NM_018674.6) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.344); catalogued as rs751452829; called by muse, mutect2, varscan2
- ATP6V1B1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 90/449 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99314410; called by muse, mutect2, varscan2
- ATP7B | c.3848C>A p.A1283D | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM164062; called by muse, mutect2, varscan2
- ATP8A1 | c.364-1G>T p.X122_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52534889; called by muse, mutect2, varscan2
- AXIN2 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs372513593, COSV100196789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMI1 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs753450025, COSV100936465; called by muse, mutect2
- BNC2 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1330774623, COSV66171716; called by muse, mutect2, varscan2
- BRCA2 | c.582G>T p.W194C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1311750; called by muse, mutect2, varscan2
- C7orf25 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV63273657, COSV63274313; called by muse, varscan2
- C9 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 309/736 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs998275622; called by muse, mutect2, varscan2
- CABIN1 | c.3464C>G p.S1155* | Nonsense Mutation (SNP) | VAF 22/178 reads (12%) | catalogued as COSV54080590, COSV99572802; called by muse, mutect2, varscan2
- CACNA1C | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV59707096; called by muse, mutect2, varscan2
- CACNG6 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV53166317; called by mutect2, varscan2
- CADPS | c.1412C>G p.A471G | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753627499; called by muse, mutect2, varscan2
- CAMSAP1 | c.3434C>T p.P1145L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56720047; called by muse, mutect2, varscan2
- CAPN14 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs375553136; called by muse, mutect2, varscan2
- CBLL2 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60369915; called by muse, mutect2, varscan2
- CCDC144A | c.2980G>T p.G994* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99062996; called by mutect2, varscan2
- CCDC168 | c.20227G>A p.E6743K | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59426730; called by muse, mutect2, varscan2
- CD300LG | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV53222412; called by muse, mutect2, varscan2
- CFAP44 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387758054; called by muse, mutect2, varscan2
- CFAP61 | c.3306C>G p.C1102W | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846532; called by muse, mutect2, varscan2
- CFH | c.3616C>A p.R1206S | Missense Mutation (SNP) | VAF 60/675 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as CM100539, COSV66410739; called by muse, mutect2
- CHD5 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs372515565, COSV52429243; called by mutect2, varscan2
- CHGB | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs756065519; called by muse, varscan2
- CHL1 | c.3527G>T p.S1176I (on ENST00000397491 / NM_001253387.1; = p.S1192I on NM_006614.4) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs141163165, COSV56591080; called by muse, mutect2, varscan2
- CHRNA4 | c.272A>C p.Q91P | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100937202; called by muse, mutect2, varscan2
- CHST8 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs754261375, COSV52858201, COSV52858327; called by muse, mutect2, varscan2
- CLSTN2 | c.2631C>A p.D877E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs995219084; called by muse, varscan2
- CLVS1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 31/132 reads (23%) | catalogued as COSV57977827, COSV57979643; called by muse, mutect2, varscan2
- CNGA2 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.099); catalogued as COSV61706232; called by muse, mutect2, varscan2
- CNTNAP5 | c.2756C>A p.T919K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as CM1010518; called by muse, mutect2
- COA6 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV64017062; called by muse, mutect2, varscan2
- COL3A1 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58585687; called by muse, mutect2, varscan2
- CORO6 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV61471824; called by muse, mutect2
- CPED1 | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs762961041; called by muse, mutect2, varscan2
- CPNE4 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV70200427; called by muse, mutect2, varscan2
- CROCC | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV100978073; called by muse, mutect2
- CTAGE1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1471752985; called by muse, mutect2, varscan2
- CTSC | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM010202; called by muse, mutect2, varscan2
- CUBN | c.6245C>A p.A2082E | Missense Mutation (SNP) | VAF 144/434 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1417686455; called by muse, mutect2, varscan2
- CUL3 | c.2176-2A>C p.X726_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV52362867; called by muse, mutect2
- CUX1 | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs782176246; called by muse, mutect2, varscan2
- CYP2C8 | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100988044; called by muse, mutect2, varscan2
- DAPK2 | c.1033-1G>A p.X345_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as rs1174097903, COSV99977414; called by muse, mutect2, varscan2
- DAPK3 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV56662772; called by muse, mutect2, varscan2
- DCAF8L1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765119036; called by muse, mutect2, varscan2
- DCTD | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs778279392, COSV63866831; called by muse, mutect2, varscan2
- DEPTOR | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV53823551; called by muse, mutect2, varscan2
- DHX9 | c.2306G>C p.R769P | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62359156; called by muse, mutect2, varscan2
- DHX9 | c.3496C>T p.R1166* | Nonsense Mutation (SNP) | VAF 27/224 reads (12%) | catalogued as COSV62358354; called by muse, mutect2
- DIP2A | c.2491G>T p.V831L | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59485014; called by muse, mutect2, varscan2
- DIPK1C | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1166352097; called by muse, mutect2, varscan2
- DLG2 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54655495; called by muse, varscan2
- DMWD | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs770454273; called by muse, mutect2, varscan2
- DNAH12 | c.5735del p.K1912Rfs*45 (on ENST00000351747; = p.K1931Rfs*45 on NM_001366028.2) | Frame Shift Del (DEL) | VAF 45/246 reads (18%) | catalogued as COSV61065296; called by pindel, varscan2*
- DNAI1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 107/401 reads (27%) | catalogued as COSV54279172; called by muse, mutect2, varscan2
- DOCK3 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56543244; called by muse, mutect2, varscan2
- DRC7 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.857); catalogued as rs532170531, COSV100395375; called by muse, mutect2, varscan2
- DST | c.22366G>T p.D7456Y (on ENST00000361203 / NM_001374722.1; = p.D5166Y on NM_015548.5) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV55009226; called by muse, mutect2, varscan2
- EDNRB | c.934A>G p.I312V (on ENST00000377211 / NM_001201397.1; = p.I222V on NM_000115.5) | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.279); catalogued as COSV57528687; called by muse, mutect2, varscan2
- EFNA5 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV60959850; called by muse, mutect2, varscan2
- EGFLAM | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV59321168; called by muse, mutect2, varscan2
- EGR1 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV53518832; called by muse, mutect2, varscan2
- EOLA2 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62207397; called by muse, mutect2, varscan2
- EPHA6 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772449969, COSV101060811; called by muse, mutect2, varscan2
- ERAP2 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs367662467, COSV101163960; called by muse, mutect2, varscan2
- ERICH6 | c.944C>G p.T315S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as COSV99901412; called by muse, mutect2, varscan2
- ERVW-1 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.096); catalogued as COSV101423809, COSV101423838; called by muse, mutect2, varscan2
- EVX2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57963245; called by muse, mutect2, varscan2
- F9 | c.178del p.E61Rfs*43 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as COSV54381187; called by mutect2, pindel, varscan2
- FAM110A | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55726786; called by muse, mutect2, varscan2
- FAM47A | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV60494966; called by muse, mutect2, varscan2
- FAM98A | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1341230632; called by muse, mutect2
- FBXO10 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV52831821; called by muse, mutect2, varscan2
- FBXO28 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100837479; called by muse, mutect2, varscan2
- FGF18 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV51126982; called by muse, mutect2, varscan2
- FLNC | c.339del p.K113Nfs*5 | Frame Shift Del (DEL) | VAF 51/237 reads (22%) | catalogued as COSV57963124; called by mutect2, pindel, varscan2
- FMNL2 | c.2942A>G p.Y981C | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437236999; called by muse, mutect2, varscan2
- FOXP2 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.899); catalogued as COSV100647426, COSV63481875; called by muse, mutect2
- FRMPD1 | c.2003A>C p.Q668P | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs962861047; called by muse, mutect2, varscan2
- GABBR2 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs868629786, COSV52293456; called by muse, mutect2, varscan2
- GALNT17 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61197411; called by muse, mutect2
- GCFC2 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV58082033; called by muse, mutect2
- GDPD5 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754450422; called by muse, mutect2, varscan2
- GPR149 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | catalogued as rs774432061, COSV67665913; called by muse, mutect2, varscan2
- GRID1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV60055047; called by muse, mutect2, varscan2
- GRIN2A | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 92/468 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs375260513; called by muse, mutect2, varscan2
- GRIN2A | c.1007+1G>C p.X336_splice | Splice Site (SNP) | VAF 56/288 reads (19%) | catalogued as CS138214, CS138239, COSV58039753; called by muse, mutect2, varscan2
- GRM5 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 108/497 reads (22%) | catalogued as COSV59609991; called by muse, mutect2, varscan2
- GUCY2D | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs762771301; called by muse, mutect2, varscan2
- HBD | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV53082700; called by muse, mutect2, varscan2
- HEPACAM2 | c.760G>T p.V254L (on ENST00000394468 / NM_001039372.4; = p.V242L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs781343055; called by muse, varscan2
- HEPH | c.379C>A p.P127T (on ENST00000343002; = p.P181T on NM_138737.5) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1188793883, COSV57960129; called by muse, mutect2, varscan2
- HKDC1 | c.1387G>T p.V463L | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100664437; called by muse, mutect2, varscan2
- HMCN1 | c.12866C>G p.P4289R | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54941589; called by muse, varscan2
- HMX1 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.697); catalogued as rs1307711414; called by muse, varscan2
- HMX1 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.161); catalogued as rs959494126; called by muse, varscan2
- HOMER1 | c.549G>C p.W183C | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV56531056; called by muse, mutect2, varscan2
- HOXA5 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.093); catalogued as rs965111568, COSV56074322; called by muse, mutect2, varscan2
- HOXB9 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs930984192; called by muse, mutect2
- HTR5A | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs764637143, COSV99839868; called by muse, mutect2, varscan2
- IFNA6 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66506635; called by muse, mutect2, varscan2
- IGKV3-7 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 112/589 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs755402947; called by muse, mutect2, varscan2
- IGLV3-1 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 35/273 reads (13%) | catalogued as rs1445064073; called by muse, mutect2, varscan2
- IGSF10 | c.6048T>A p.C2016* | Nonsense Mutation (SNP) | VAF 57/230 reads (25%) | catalogued as COSV56397280; called by muse, mutect2, varscan2
- IL36B | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV52084362; called by muse, mutect2, varscan2
- IL36RN | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 88/489 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1269646424; called by muse, varscan2
- IL5RA | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as COSV56526453; called by muse, mutect2, varscan2
- INPP4B | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99527288; called by muse, mutect2, varscan2
- ITGA8 | c.2299A>C p.K767Q | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.544); catalogued as COSV65232199; called by muse, mutect2, varscan2
- ITGAX | c.2789G>T p.S930I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51652222; called by muse, mutect2, varscan2
- ITGB2 | c.2313del p.W771* (on ENST00000302347; = p.W747* on NM_000211.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 95/456 reads (21%) | catalogued as COSV56609181; called by mutect2, pindel, varscan2
- KCNK15 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as rs367808576, COSV100865201; called by muse, mutect2, varscan2
- KDR | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV55774079, COSV99818211; called by muse, mutect2, varscan2
- KIF2B | c.1847C>A p.S616Y | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52127696; called by muse, mutect2, varscan2
- KRTAP4-9 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1209459912; called by muse, mutect2
- KRTAP4-9 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66950600; called by muse, mutect2, varscan2
- LAMA1 | c.5329del p.E1777Kfs*13 | Frame Shift Del (DEL) | VAF 101/352 reads (29%) | catalogued as COSV67541572; called by mutect2, pindel, varscan2
- LBP | c.368+2T>A p.X123_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as rs112598125; called by muse, mutect2, varscan2
- LCE3D | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 38/698 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.339); catalogued as rs201921868, COSV64230604; called by muse, mutect2
- LIMS2 | c.131C>A p.A44D (on ENST00000355119 / NM_001161403.3; = p.A68D on NM_017980.4) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55757233; called by muse, mutect2
- LMF1 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs199544373; called by muse, mutect2, varscan2
- LRFN5 | c.1531del p.E511Nfs*19 | Frame Shift Del (DEL) | VAF 112/275 reads (41%) | catalogued as COSV53279470; called by mutect2, pindel, varscan2
- LRFN5 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 147/311 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs184300558; called by muse, mutect2, varscan2
- LUZP2 | c.955T>A p.C319S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV61208432; called by muse, mutect2, varscan2
- MAP3K4 | c.136T>A p.C46S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as rs371606483; called by muse, mutect2, varscan2
- MARCHF6 | c.1699del p.H567Ifs*61 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | catalogued as COSV99929960; called by mutect2, pindel, varscan2
- MASP1 | c.819C>G p.H273Q | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV51459872; called by muse, varscan2
- MATN2 | c.714G>A p.T238= | Splice Region (SNP) | VAF 30/204 reads (15%) | catalogued as rs761834193; called by muse, mutect2, varscan2
- MIB1 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766332514; called by muse, mutect2, varscan2
- MLN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs370254845; called by muse, mutect2, varscan2
- MLPH | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV52822440; called by muse, varscan2
- MSC | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100335583; called by muse, mutect2, varscan2
- MUC12 | c.9080C>G p.T3027R (on ENST00000379442; = p.T2884R on NM_001164462.1) | Missense Mutation (SNP) | VAF 113/3890 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65192236; called by muse, mutect2
- MUC17 | c.4909C>A p.P1637T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs769346448; called by muse, varscan2
- MUC17 | c.8677C>G p.P2893A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as rs1421346265; called by muse, mutect2, varscan2
- MYEF2 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.469); catalogued as rs370663684; called by muse, mutect2
- MYF6 | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57352408; called by muse, mutect2, varscan2
- MYH1 | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1567719046; called by muse, mutect2, varscan2
- MYLK3 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs749607925; called by muse, mutect2, varscan2
- MYO18B | c.4916G>A p.W1639* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV59150333; called by muse, mutect2, varscan2
- MYO1F | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866917226, COSV100596536; called by muse, mutect2, varscan2
- NAT2 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs1252922818; called by muse, mutect2, varscan2
- NCOA6 | c.5137G>T p.V1713L | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV62861094; called by muse, mutect2
- NDST1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV55791384; called by muse, mutect2, varscan2
- NEK2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | catalogued as COSV65355689; called by muse, mutect2, varscan2
- NLRP3 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 89/395 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV60223635; called by muse, mutect2, varscan2
- NLRP7 | c.2647C>T p.Q883* (on ENST00000340844 / NM_206828.3; = p.Q855* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 52/218 reads (24%) | catalogued as rs755890731; called by muse, mutect2, varscan2
- NLRP7 | c.2640G>T p.L880F (on ENST00000340844 / NM_206828.3; = p.L852F on NM_139176.3) | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140610927, COSV100053474; called by muse, varscan2
- NOMO2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs1376784721; called by mutect2, varscan2
- NOS2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100569767; called by muse, mutect2, varscan2
- NOTCH1 | c.5008G>T p.D1670Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1157456139; called by muse, mutect2, varscan2
- NPHS1 | c.2815+2T>C p.X939_splice | Splice Site (SNP) | VAF 65/327 reads (20%) | catalogued as CS044966; called by muse, mutect2, varscan2
- NPLOC4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as rs1378278966, COSV58618874; called by muse, varscan2
- NR0B1 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CD147678; called by muse, mutect2, varscan2
- NSG2 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100292967; called by muse, mutect2, varscan2
- ODF4 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs1422998726; called by muse, varscan2
- OR10T2 | c.367C>G p.R123G | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV57781131, COSV57782220; called by muse, mutect2, varscan2
- OR11L1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869509, COSV99053953; called by muse, mutect2, varscan2
- OR13G1 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | catalogued as COSV62943568; called by muse, mutect2
- OR2B2 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57580535; called by muse, mutect2, varscan2
- OR2C3 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs562326145, COSV63574257, COSV63574402, COSV63574958; called by muse, varscan2
- OR2M2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV62898689; called by muse, mutect2, varscan2
- OR4A16 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.109); catalogued as COSV59042576; called by muse, mutect2, varscan2
- OR4S1 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60679849; called by muse, mutect2, varscan2
- OR51F1 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.915); catalogued as COSV100598830; called by muse, mutect2
- OR52R1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1479675712; called by muse, mutect2, varscan2
- OR5F1 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV53546722; called by muse, mutect2, varscan2
- OR5J2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 30/233 reads (13%) | catalogued as COSV100399164; called by muse, mutect2, varscan2
- OR6K2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 86/426 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558008726; called by muse, mutect2, varscan2
- OR6Y1 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as rs896183361; called by muse, varscan2
- OR6Y1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV100225532; called by muse, varscan2
- OR8H1 | c.281T>A p.M94K | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57295560; called by muse, mutect2, varscan2
- OR8K5 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs201565179; called by muse, mutect2, varscan2
- OSBPL7 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136709; called by muse, mutect2, varscan2
- OTOA | c.2403A>T p.E801D (on ENST00000286149; = p.E787D on NM_144672.4) | Missense Mutation (SNP) | VAF 99/472 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV53760943; called by muse, mutect2, varscan2
- OTOR | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as rs771250120; called by muse, mutect2, varscan2
- OTUD4 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.773); catalogued as rs1387065251; called by muse, mutect2, varscan2
- PABPC5 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57040504; called by muse, mutect2, varscan2
- PAPPA2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1322260361, COSV62775495; called by muse, mutect2, varscan2
- PCDHA5 | c.522C>G p.N174K | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV100972726; called by muse, mutect2, varscan2
- PCDHB12 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV53400562; called by muse, varscan2
- PCDHB2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV99523052; called by muse, mutect2, varscan2
- PCDHGA12 | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); catalogued as rs773899530, COSV99340665; called by muse, mutect2
- PCDHGA4 | c.1178C>A p.P393Q | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as rs1405876688; called by muse, mutect2, varscan2
- PCDHGB7 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs375588252; called by muse, mutect2, varscan2
- PDE3A | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs372633417; called by muse, mutect2, varscan2
- PDE3B | c.2476C>A p.P826T | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56389447, COSV99962032; called by muse, mutect2, varscan2
- PDHA2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54780595; called by muse, mutect2, varscan2
- PDZRN4 | c.1438G>T p.V480L (on ENST00000402685 / NM_001164595.2; = p.V222L on NM_013377.4) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV54212937; called by muse, mutect2, varscan2
- PEAK1 | c.2354A>C p.Q785P | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761891943; called by muse, mutect2, varscan2
- PKNOX2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53548204; called by muse, mutect2, varscan2
- PKP1 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs766109517; called by muse, mutect2, varscan2
- PLA2G2F | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs759630010, COSV64279835, COSV64279863; called by muse, mutect2, varscan2
- PLCB1 | c.2891C>A p.A964D | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100569348; called by muse, mutect2, varscan2
- PLCB1 | c.3058C>T p.R1020W | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1023330264, COSV62039726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHF2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59541220; called by muse, mutect2
- PLOD2 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51467661; called by muse, mutect2, varscan2
- PLPP4 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100956620; called by muse, mutect2, varscan2
- PPP1R13L | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs141585259; called by muse, mutect2, varscan2
- PRAMEF17 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 77/389 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1489123581; called by muse, mutect2, varscan2
- PSD4 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs1473484969; called by muse, mutect2, varscan2
- PSME4 | c.2946G>A p.V982= | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as rs766320528, COSV101122535; called by muse, mutect2, varscan2
- PSRC1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 29/210 reads (14%) | catalogued as rs773654464; called by muse, mutect2, varscan2
- PTPRC | c.1805A>G p.Y602C | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs370560920; called by muse, mutect2, varscan2
- PTPRD | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61924848; called by muse, mutect2, varscan2
- PTPRQ | c.6809G>A p.S2270N (on ENST00000616559; = p.S2237N on NM_001145026.2) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs1285482129; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs374416247; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57931659; called by muse, mutect2, varscan2
- RALYL | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.827); catalogued as COSV72819622; called by muse, mutect2
- RBBP4 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65133544; called by mutect2, varscan2
- RBP3 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1045075808; called by muse, mutect2, varscan2
- RBPJL | c.1302C>A p.C434* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as rs1333952891, COSV100643481, COSV59212787; called by muse, mutect2
- RGS9 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 151/431 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1211803356; called by muse, mutect2, varscan2
- RHEX | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV100520120; called by muse, mutect2
- RIMS1 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53469571; called by muse, mutect2, varscan2
- RNF17 | c.784A>T p.I262F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55047110; called by muse, varscan2
- RNF17 | c.3686G>T p.W1229L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55033406; called by muse, mutect2, varscan2
- RNPC3 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as rs748883771; called by muse, mutect2, varscan2
- RP1L1 | c.1275G>T p.R425S | Missense Mutation (SNP) | VAF 96/356 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs771615406; called by muse, mutect2, varscan2
- RPL3L | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51905039; called by muse, mutect2, varscan2
- RPUSD3 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67579283; called by muse, mutect2, varscan2
- SERPINA6 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 160/434 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100448377; called by muse, mutect2, varscan2
- SERPINB7 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs758594172; called by muse, varscan2
- SESN3 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 31/276 reads (11%) | catalogued as COSV53585103; called by muse, mutect2, varscan2
- SIDT2 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54055341, COSV54055352; called by muse, mutect2, varscan2
- SIN3B | c.2998G>T p.A1000S | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV56134742; called by muse, mutect2, varscan2
- SLC39A10 | c.1570_1572del p.Q524del | In Frame Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs778206324; called by pindel, varscan2
- SLC4A3 | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV56097913; called by muse, mutect2
- SLC52A2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 66/447 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV100096244; called by muse, mutect2, varscan2
- SMARCA2 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV61810282; called by muse, mutect2, varscan2
- SNTG1 | c.976T>A p.W326R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.986); catalogued as COSV52426987; called by muse, mutect2
- SPATA5 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV56783489; called by muse, mutect2, varscan2
- SPEG | c.9361C>A p.R3121S | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.826); catalogued as COSV100405963; called by muse, mutect2, varscan2
- SPOCD1 | c.2869G>T p.G957W | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930446; called by muse, mutect2, varscan2
- SPR | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024333245, CM0911431, COSV52298629; called by muse, mutect2, varscan2
- SPRN | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs559920556; called by muse, varscan2
- SPSB4 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV60147379; called by muse, mutect2, varscan2
- SPSB4 | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV60148120; called by muse, mutect2, varscan2
- SRBD1 | c.1352del p.K451Rfs*8 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as COSV55396366; called by mutect2, pindel, varscan2
- STAG3 | c.2061+1G>C p.X687_splice | Splice Site (SNP) | VAF 19/129 reads (15%) | catalogued as COSV57934041; called by muse, mutect2, varscan2
- STAP1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55330958; called by muse, mutect2, varscan2
- STK10 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | catalogued as COSV51581056; called by muse, mutect2, varscan2
- STYXL2 | c.3283T>A p.S1095T | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV54805532; called by muse, mutect2, varscan2
- SUCO | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199640710, COSV55262199; called by muse, varscan2
- SULF1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52684275; called by muse, mutect2, varscan2
- SYCP1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65698859; called by muse, varscan2
- SYT14 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 40/503 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55059285; called by muse, mutect2
- TAF15 | c.1223G>T p.R408L (on ENST00000605844 / NM_139215.3; = p.R405L on NM_003487.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.129); catalogued as rs376580614; called by muse, mutect2, varscan2
- TAS2R41 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759457614, COSV68765253; called by muse, mutect2, varscan2
- TBX21 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99456043; called by muse, mutect2
- TBX5 | c.1387C>A p.H463N | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV59864434; called by muse, mutect2, varscan2
- TBX5 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs751532982, COSV100092500; called by muse, mutect2, varscan2
- TDRD5 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54242284; called by muse, varscan2
- TDRD5 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99038831; called by muse, mutect2, varscan2
- TENM2 | c.6878C>A p.A2293D (on ENST00000518659 / NM_001122679.2; = p.A2054D on NM_001080428.3) | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as rs1207012807; called by muse, mutect2, varscan2
- TESPA1 | c.937G>T p.D313Y (on ENST00000316577 / NM_001098815.3; = p.D175Y on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100345565; called by muse, mutect2, varscan2
- TEX14 | c.2545C>G p.Q849E (on ENST00000240361 / NM_001201457.2; = p.Q843E on NM_031272.5) | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs199821469; called by muse, mutect2
- TEX36 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV64315725; called by muse, mutect2, varscan2
- TEX47 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV99787403; called by muse, mutect2, varscan2
- TGS1 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs773701156; called by muse, mutect2, varscan2
- THSD1 | c.1865A>G p.Q622R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs866691313; called by muse, mutect2, varscan2
- THSD7A | c.1879T>C p.C627R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441832680; called by muse, mutect2, varscan2
- TIAM2 | c.2599C>A p.P867T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100020232; called by muse, mutect2, varscan2
- TIGD5 | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57820966; called by muse, mutect2
- TMC5 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as rs767276984, COSV66867347; called by muse, mutect2, varscan2
- TMTC1 | c.2308G>T p.A770S (on ENST00000539277 / NM_001193451.2; = p.A662S on NM_175861.3) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs758498492; called by muse, mutect2, varscan2
- TNN | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 89/480 reads (19%) | catalogued as rs1204656551, COSV53431283; called by muse, mutect2, varscan2
- TNRC6C | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1027519598, COSV56943308; called by muse, mutect2
- TOPAZ1 | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100554891; called by mutect2, varscan2
- TP53TG5 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 62/456 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.048); catalogued as COSV65576895; called by muse, mutect2, varscan2
- TRAT1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.801); catalogued as COSV55467542; called by muse, mutect2, varscan2
- TRHDE | c.2276G>T p.R759L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV53830756, COSV53833514; called by muse, mutect2, varscan2
- TRHR | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 188/478 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as rs368688599; called by muse, mutect2, varscan2
- TRHR | c.889del p.Q297Kfs*22 | Frame Shift Del (DEL) | VAF 67/397 reads (17%) | catalogued as COSV61234902; called by mutect2, pindel, varscan2
- TRIM58 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 35/510 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.139); catalogued as rs761929755, COSV63572621; called by muse, mutect2
- TRIM62 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs768491697, COSV99357735; called by muse, mutect2, varscan2
- TRPM5 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774051811, COSV50149852; called by muse, mutect2, varscan2
- TSSK1B | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66816162; called by muse, mutect2, varscan2
- TTC24 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 98/474 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1259036837; called by muse, mutect2, varscan2
- TUBA3C | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs780474312, COSV67140258; called by muse, mutect2, varscan2
- TUBB4A | c.728C>A p.P243Q | Missense Mutation (SNP) | VAF 91/610 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV99899976; called by muse, mutect2, varscan2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- UGT3A1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as rs1188515955; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV54435438; called by muse, mutect2, varscan2
- USH2A | c.14802C>A p.Y4934* | Nonsense Mutation (SNP) | VAF 47/433 reads (11%) | catalogued as CM165985; called by muse, mutect2, varscan2
- USH2A | c.1900G>T p.A634S | Missense Mutation (SNP) | VAF 58/604 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.817); catalogued as rs759589036, COSV100245191; ClinVar: uncertain significance; called by muse, mutect2
- USP26 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); catalogued as rs1161749506; called by muse, mutect2, varscan2
- USP29 | c.1741A>G p.M581V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs370590594; called by muse, mutect2, varscan2
- UTRN | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs748671773, COSV62331711; called by muse, mutect2, varscan2
- UTRN | c.9835G>T p.V3279L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs748250479; called by muse, varscan2
- VANGL2 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 164/755 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as rs1024334237; called by muse, mutect2, varscan2
- VGF | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as rs1411097222; called by muse, mutect2, varscan2
- VSTM1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as rs779173655, COSV100618711, COSV100618867; called by muse, mutect2, varscan2
- WDR26 | c.1166A>G p.Y389C (on ENST00000414423 / NM_001379403.1; = p.Y289C on NM_025160.7) | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV54357179; called by muse, mutect2
- WDR92 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV54561598, COSV99718533; called by muse, mutect2, varscan2
- XIRP2 | c.6557C>T p.S2186L (on ENST00000628543; = p.S2361L on NM_152381.6) | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV54687532; called by muse, mutect2, varscan2
- XIRP2 | c.8110A>T p.S2704C (on ENST00000628543; = p.S2879C on NM_152381.6) | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV54699395; called by muse, mutect2
- XKR6 | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58660172; called by muse, mutect2, varscan2
- XPNPEP2 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs147873278, COSV64367848; called by muse, mutect2, varscan2
- ZBTB17 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs1350046192, COSV65270496; called by muse, mutect2, varscan2
- ZFAT | c.3161G>T p.W1054L | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64738157; called by muse, mutect2, varscan2
- ZFHX4 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.127); catalogued as rs745707914, COSV50652406; called by muse, mutect2, varscan2
- ZMIZ2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54810920; called by muse, mutect2, varscan2
- ZNF229 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV52161190, COSV99349862; called by mutect2, varscan2
- ZNF492 | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1208000425, COSV101513916; called by muse, varscan2
- ZNF536 | c.3818C>A p.S1273Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV62827382, COSV99052783; called by muse, mutect2, varscan2
- ZNF57 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs371789463, COSV60983996; called by muse, mutect2, varscan2
- ZNF654 | c.2867T>C p.I956T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100525780; called by muse, mutect2, varscan2
- ZNF843 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.291); catalogued as rs866162007; called by muse, mutect2, varscan2
- ZNF98 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV100757377, COSV63340613; called by muse, mutect2, varscan2
- ABCA13 | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCC2 | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ABCD2 | c.1019A>T p.Y340F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ABHD18 | c.703del p.D235Ifs*10 (on ENST00000398965 / NM_001039717.2; = p.D142Ifs*10 on NM_025097.2 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- ABI3 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACP7 | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSL4 | c.1826A>T p.Q609L (on ENST00000340800 / NM_022977.2; = p.Q568L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, varscan2
- ACSM1 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 103/472 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSM2A | c.431del p.D144Afs*34 (on ENST00000219054; = p.D65Afs*34 on NM_001308169.2) | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | called by mutect2, pindel*, varscan2
- ACTA1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); called by muse, mutect2
- ACTN2 | c.1554C>A p.H518Q | Missense Mutation (SNP) | VAF 131/527 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ACTN2 | c.1739A>T p.N580I | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ADAM18 | c.1179T>A p.C393* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- ADAM19 | c.2530C>G p.P844A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, varscan2
- ADAM9 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS10 | c.2713C>A p.R905S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ADAMTS6 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ADAMTS8 | c.2345T>G p.L782W | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ADCY1 | c.830T>C p.M277T | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY2 | c.1546A>G p.M516V | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRA3 | c.3353dup p.L1118Ffs*22 | Frame Shift Ins (INS) | VAF 15/131 reads (11%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AFF1 | c.1768G>T p.A590S | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- AGER | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGFG2 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AHNAK2 | c.7352T>A p.V2451E | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.3845T>C p.V1282A | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- AKAP6 | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- AL121899.2 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); called by muse, varscan2
- ALDH2 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3A1 | c.851G>C p.R284T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ALK | c.3031G>T p.G1011W | Missense Mutation (SNP) | VAF 96/425 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALMS1 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALPK1 | c.2164del p.W722Gfs*25 | Frame Shift Del (DEL) | VAF 30/216 reads (14%) | called by mutect2, pindel, varscan2
- AMER3 | c.1268A>T p.Y423F | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- AMHR2 | c.1409G>T p.W470L | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANAPC1 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ANGPTL5 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ANGPTL7 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 23/230 reads (10%) | called by muse, mutect2
- ANK1 | c.3562A>G p.I1188V | Missense Mutation (SNP) | VAF 147/490 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ANK2 | c.9273G>T p.E3091D | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANK3 | c.995A>T p.K332M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1510A>T p.T504S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD17 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, varscan2
- ANKRD24 | c.2635del p.D879Tfs*131 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD36B | c.1912A>T p.K638* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- ANKRD36C | c.2839G>T p.G947* | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- ANKRD50 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKRD53 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ANP32E | c.293del p.N98Tfs*3 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | called by mutect2, pindel, varscan2
- ANPEP | c.2360+1G>T p.X787_splice | Splice Site (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- AP3B1 | c.3178G>T p.V1060L | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- APC2 | c.6770C>G p.P2257R | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2
- APOB | c.9613G>C p.D3205H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- APOB | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 121/541 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- APP | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARC | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ARHGEF18 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ARHGEF33 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASAP2 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ASB3 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASPG | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ATP1A3 | c.640T>A p.C214S (on ENST00000545399 / NM_001256214.2; = p.C201S on NM_152296.5) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ATP6V0D2 | c.860A>T p.K287M | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRNL1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- B2M | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 95/265 reads (36%) | called by muse, varscan2
- BACH2 | c.984C>G p.C328W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- BAHCC1 | c.2191G>T p.G731C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- BAHCC1 | c.3427A>T p.R1143W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- BAZ2B | c.1909A>T p.S637C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- BCAN | c.2210-5C>T | Splice Region (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
- BEND4 | c.525C>G p.C175W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEX4 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2
- BMPR1B | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 35/298 reads (12%) | called by muse, mutect2, varscan2
- BMX | c.1971del p.T658Hfs*50 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel, varscan2
- BPIFB6 | c.153dup p.G52Rfs*74 | Frame Shift Ins (INS) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- BTBD6 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- BTNL3 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- C10orf62 | c.195del p.S66Vfs*10 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- C11orf21 | c.322G>T p.D108Y (on ENST00000381153 / NM_001329958.2; = p.D154Y on NM_001142946.3) | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- C1orf87 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- C1orf94 | c.902C>A p.P301H (on ENST00000488417 / NM_001134734.2; = p.P111H on NM_032884.5) | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- C3orf20 | c.529A>T p.S177C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C3orf20 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- C7orf25 | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CACHD1 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CACNA2D1 | c.3197A>T p.E1066V (on ENST00000356253 / NM_001366867.1; = p.E1054V on NM_000722.4) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CACNA2D4 | c.2383C>A p.L795M | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CACNB4 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- CAMKK1 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND2 | c.2876G>A p.C959Y (on ENST00000456430 / NM_001162499.2; = p.C866Y on NM_012298.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN7 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- CARD6 | c.1790A>T p.Q597L | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CARNS1 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CASP14 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASR | c.2812C>T p.P938S (on ENST00000490131; = p.P1015S on NM_000388.4) | Missense Mutation (SNP) | VAF 46/496 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); called by muse, mutect2
- CATSPERG | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC102A | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- CCDC166 | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CCP110 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2
- CCR3 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCSER1 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCT6B | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2
- CD44 | c.1775G>C p.G592A | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDH23 | c.4228G>T p.D1410Y | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR2 | c.2605del p.A869Rfs*31 | Frame Shift Del (DEL) | VAF 86/289 reads (30%) | called by mutect2, pindel, varscan2
- CDKL5 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); called by muse, mutect2
- CDRT15L2 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CENPC | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CEP104 | c.1718A>T p.Q573L | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, varscan2
- CEP131 | c.2278G>T p.E760* (on ENST00000269392 / NM_001319228.2; = p.E757* on NM_014984.4) | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- CEP170 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 41/469 reads (9%) | called by muse, mutect2
- CEP290 | c.2753A>T p.K918M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- CFAP44 | c.4646_4647dup p.E1550Lfs*18 | Frame Shift Ins (INS) | VAF 89/401 reads (22%) | called by pindel, varscan2*
- CFAP44 | c.2129T>G p.L710R | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CFAP47 | c.2686A>T p.I896L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CFAP54 | c.7685-1G>C p.X2562_splice | Splice Site (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- CFAP61 | c.2734C>G p.P912A | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CFAP92 | c.2493C>A p.D831E | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CHAF1A | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHL1 | c.2536C>A p.Q846K (on ENST00000397491 / NM_001253387.1; = p.Q862K on NM_006614.4) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CHRDL2 | c.214T>A p.Y72N | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CHRNA10 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 68/268 reads (25%) | called by muse, varscan2
- CHRNB3 | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CLEC16A | c.2140A>T p.T714S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- CLIP1 | c.4066G>T p.G1356W (on ENST00000620786 / NM_001247997.1; = p.G1345W on NM_002956.2) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CLNS1A | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- CLP1 | c.723del p.L242Wfs*25 | Frame Shift Del (DEL) | VAF 44/186 reads (24%) | called by mutect2, pindel, varscan2
- CMKLR1 | c.1025C>G p.T342R (on ENST00000312143 / NM_001142344.2; = p.T340R on NM_004072.3) | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CMYA5 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CNGA3 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CNN1 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN2 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- CNTN3 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CNTNAP4 | c.839dup p.L280Ffs*28 | Frame Shift Ins (INS) | VAF 49/204 reads (24%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- COL10A1 | c.1038dup p.G347Rfs*8 | Frame Shift Ins (INS) | VAF 56/223 reads (25%) | called by mutect2, pindel, varscan2
- COL12A1 | c.8942-2A>T p.X2981_splice | Splice Site (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- COL22A1 | c.2701-2A>T p.X901_splice | Splice Site (SNP) | VAF 119/298 reads (40%) | called by muse, mutect2, varscan2
- COL6A1 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- COL6A5 | c.4400G>T p.G1467V | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL6A6 | c.3106A>G p.R1036G | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- COPB1 | c.1118A>G p.H373R | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CPB1 | c.287dup p.N96Kfs*11 | Frame Shift Ins (INS) | VAF 49/179 reads (27%) | called by mutect2, pindel, varscan2
- CPNE3 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CPNE5 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CPQ | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2
- CR1L | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.223); called by muse, mutect2
- CRYBG2 | c.163T>A p.F55I | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CSF2RB | c.2200C>G p.L734V | Missense Mutation (SNP) | VAF 68/351 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CSMD3 | c.2774T>A p.I925N (on ENST00000297405 / NM_001363185.1; = p.I821N on NM_052900.3) | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSNK1D | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 214/597 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CUL9 | c.2141A>T p.E714V | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CUX2 | c.1888G>C p.V630L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CWH43 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYP26C1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP51A1 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by mutect2, varscan2
- DACH1 | c.1726+1G>T p.X576_splice (on ENST00000619232 / NM_001366712.1; = p.X524_splice on NM_080759.6) | Splice Site (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- DACT1 | c.1943G>C p.G648A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCC | c.3091G>T p.G1031W | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCLK1 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DEFB121 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DEFB125 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DHH | c.1063C>A p.R355S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- DISP3 | c.1221C>G p.N407K | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DLC1 | c.4477C>G p.P1493A (on ENST00000276297 / NM_001348081.2; = p.P1056A on NM_006094.5) | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DMD | c.7915G>T p.V2639L | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- DNAH10 | c.7471C>T p.H2491Y (on ENST00000409039; = p.H2430Y on NM_207437.3) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DNAH11 | c.4960del p.A1654Pfs*65 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- DNAH11 | c.6712T>C p.F2238L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DNAH3 | c.10786G>T p.E3596* | Nonsense Mutation (SNP) | VAF 75/270 reads (28%) | called by muse, mutect2, varscan2
- DNAH3 | c.9908C>A p.T3303N | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- DNAH5 | c.10765C>G p.Q3589E | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- DNAH6 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB6 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DNM1L | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- DOCK5 | c.3800A>T p.H1267L | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DPY19L3 | c.1851G>T p.K617N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPYSL3 | c.494T>G p.M165R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DRD1 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DROSHA | c.4048C>A p.Q1350K | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DSP | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DST | c.2066A>G p.N689S (on ENST00000361203 / NM_001374722.1; = p.N363S on NM_001723.6) | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- DTNA | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, varscan2
- DUSP15 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2
- DUXA | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DYRK2 | c.1572G>T p.M524I (on ENST00000344096 / NM_006482.3; = p.M451I on NM_003583.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.08); called by muse, mutect2
- DYRK4 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2118del p.K707Rfs*3 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- EEF2K | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EFR3A | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EHMT2 | c.2483C>A p.T828K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- EIF2AK2 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, varscan2
- EIF4G3 | c.2903G>T p.R968M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAVL2 | c.230-1G>T p.X77_splice | Splice Site (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- ELF1 | c.1259C>G p.T420S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by muse, mutect2
- ELF5 | c.256T>A p.C86S (on ENST00000312319 / NM_198381.2; = p.C76S on NM_001422.4) | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- EML1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ENTPD5 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ENTPD6 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EPB41L2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EPHA3 | c.1550A>T p.Y517F | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHA7 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8L3 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ERCC6 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ERVMER34-1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- EXOC6B | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EYS | c.6493C>G p.L2165V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2
- EYS | c.2322G>T p.E774D | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAIM2 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM151B | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, varscan2
- FAM171A1 | c.2097del p.K700Sfs*45 | Frame Shift Del (DEL) | VAF 37/276 reads (13%) | called by pindel, varscan2
- FAM171B | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM47B | c.88T>A p.F30I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM9A | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- FAT3 | c.9568G>C p.E3190Q | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.10390A>T p.S3464C | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT3 | c.11111C>A p.A3704E | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- FAT4 | c.7327G>C p.G2443R | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.6913T>C p.C2305R | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FBXO40 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FBXO40 | c.1918T>A p.W640R | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCAR | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FCRL3 | c.1164G>T p.R388S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.305); called by muse, mutect2
- FCRL5 | c.830G>T p.W277L | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.145); called by muse, varscan2
- FCRLB | c.52+2T>G p.X18_splice | Splice Site (SNP) | VAF 29/244 reads (12%) | called by muse, mutect2, varscan2
- FER | c.542T>C p.L181S | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FER1L6 | c.1317G>C p.K439N | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FKRP | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG | c.11453A>T p.Q3818L | Missense Mutation (SNP) | VAF 200/898 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FLG2 | c.1451C>A p.S484Y | Missense Mutation (SNP) | VAF 64/494 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FLNB | c.1063A>C p.S355R | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FLT3 | c.2206A>C p.S736R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOLR3 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FREM3 | c.2705A>T p.Y902F | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FRY | c.6732G>C p.Q2244H | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSCN3 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FST | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- GABARAPL2 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- GAL3ST2 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- GALNT17 | c.1379A>T p.Y460F | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GBP7 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- GCN1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- GEMIN5 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GEMIN5 | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GJA5 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GLI1 | c.2601G>T p.Q867H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GLO1 | c.467-14_475del p.X156_splice | Splice Site (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPATCH8 | c.157T>A p.W53R | Missense Mutation (SNP) | VAF 161/457 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPC5 | c.937G>T p.G313* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- GPC5 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR1 | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR151 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR153 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GPR158 | c.1064A>T p.K355I | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GPR158 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2
- GRID2IP | c.1882C>A p.H628N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN3A | c.1915A>T p.S639C | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSX2 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GUCY2D | c.2399A>T p.H800L | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- H6PD | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 100/389 reads (26%) | called by muse, mutect2, varscan2
- HAUS6 | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- HCRTR2 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- HEATR5B | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HERC2 | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2, varscan2
- HIBCH | c.404A>T p.Y135F | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HIVEP3 | c.6026G>T p.S2009I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HIVEP3 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HMCN2 | c.12559G>T p.G4187W | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCS1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMX1 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HOXA1 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.014); called by muse, varscan2
- HOXA10 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HOXA9 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HS3ST2 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HSD17B4 | c.1337del p.X446_splice (on ENST00000414835 / NM_001199291.3; = p.X421_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 11/114 reads (10%) | called by mutect2, pindel, varscan2
- HSFX2 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by mutect2, varscan2
- HTT | c.7826G>T p.S2609I | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- HTT | c.9016C>T p.Q3006* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- IGFN1 | c.2919+1G>A p.X973_splice (on ENST00000295591 / NM_001367841.1; = p.X3430_splice on NM_001164586.2) | Splice Site (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- IGHG3 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 159/375 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGKV1-8 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IL12RB1 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL17RA | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 83/539 reads (15%) | called by muse, mutect2, varscan2
- IL17RD | c.1673A>T p.D558V | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IL7R | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 109/464 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5D | c.2779C>A p.L927M (on ENST00000445964 / NM_001017915.3; = p.L926M on NM_005541.5) | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); called by muse, mutect2
- INTS4 | c.201A>T p.E67D | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.29A>C p.Q10P | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IQCK | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IQGAP1 | c.4436A>T p.Q1479L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ITGA1 | c.75C>G p.C25W | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ITGA2 | c.1915G>C p.G639R | Missense Mutation (SNP) | VAF 75/417 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA2B | c.1394-2A>G p.X465_splice | Splice Site (SNP) | VAF 248/664 reads (37%) | called by muse, mutect2, varscan2
- ITGAE | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ITGAL | c.1772T>A p.L591H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGAX | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ITSN1 | c.1212A>T p.K404N | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- IVL | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 132/475 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAG1 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- JPH4 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 35/159 reads (22%) | called by muse, mutect2, varscan2
- KBTBD8 | c.552_553delinsT p.K184Nfs*8 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | called by pindel, varscan2*
- KCNIP4 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK15 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- KCNT2 | c.3112C>A p.Q1038K | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KCTD8 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, varscan2
- KCTD8 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2
- KIAA0895 | c.695C>T p.S232F (on ENST00000297063 / NM_001100425.2; = p.S181F on NM_015314.3) | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KIF16B | c.665G>T p.R222M | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF21B | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 30/273 reads (11%) | called by muse, mutect2, varscan2
- KIF6 | c.2058G>A p.W686* | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- KLF17 | c.1132_1134del p.N378del | In Frame Del (DEL) | VAF 53/230 reads (23%) | called by mutect2, pindel, varscan2
- KLHDC7A | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KLHL14 | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- KLHL18 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KLHL2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- KMT2B | c.2201A>T p.Q734L | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2B | c.6847A>T p.T2283S | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KNCN | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KNOP1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRIT1 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT13 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KRT85 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 59/600 reads (10%) | called by muse, mutect2
- KRT85 | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 58/600 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2
- KRTAP10-4 | c.157del p.L53* | Frame Shift Del (DEL) | VAF 60/441 reads (14%) | called by mutect2, varscan2
- KRTAP10-7 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 96/770 reads (12%) | called by muse, mutect2, varscan2
- KRTAP4-6 | c.91T>A p.C31S | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- KRTAP9-7 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 138/424 reads (33%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- L1CAM | c.3325C>A p.R1109S | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- L3MBTL1 | c.1952G>T p.G651V (on ENST00000418998 / NM_001377303.1; = p.G561V on NM_015478.7) | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA1 | c.1625A>T p.Q542L | Missense Mutation (SNP) | VAF 110/424 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LAMA1 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LAMB4 | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- LCT | c.1332C>G p.C444W | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LDLRAD4 | c.363C>G p.S121R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LGI1 | c.1131C>A p.Y377* | Nonsense Mutation (SNP) | VAF 60/302 reads (20%) | called by muse, mutect2, varscan2
- LHFPL6 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIG4 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIN9 | c.1256G>T p.R419I (on ENST00000366808 / NM_001270410.2; = p.R364I on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- LLGL2 | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMNB2 | c.868A>T p.K290* | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- LNPEP | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, varscan2
- LONP1 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, varscan2
- LOXHD1 | c.3402G>T p.Q1134H | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- LOXHD1 | c.21G>C p.R7S | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- LRFN2 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- LRGUK | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- LRIT3 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.12569C>T p.S4190F | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LRRC18 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- LRRC3B | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- LRRC4C | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC72 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- LSMEM2 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LSMEM2 | c.252T>A p.C84* | Nonsense Mutation (SNP) | VAF 38/201 reads (19%) | called by muse, mutect2, varscan2
- LY6D | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 44/300 reads (15%) | called by muse, mutect2, varscan2
- LYPD5 | c.253C>A p.Q85K (on ENST00000377950 / NM_001031749.3; = p.Q42K on NM_182573.2) | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYST | c.10321G>T p.V3441L | Missense Mutation (SNP) | VAF 49/570 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- MAGEA11 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MAGEA8 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MAGEC2 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MANBA | c.339A>T p.E113D | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP2K3 | c.637G>T p.G213C (on ENST00000342679 / NM_145109.3; = p.G184C on NM_002756.4) | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K8 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP4 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MARCHF11 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MARCHF4 | c.92T>A p.M31K | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- MARK1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2
- MARK1 | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MATK | c.748C>A p.L250M (on ENST00000310132 / NM_139355.3; = p.L251M on NM_002378.4) | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MATN2 | c.1770C>A p.C590* | Nonsense Mutation (SNP) | VAF 39/262 reads (15%) | called by muse, mutect2, varscan2
- MBLAC1 | c.758A>T p.Q253L | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCM10 | c.1936C>T p.P646S (on ENST00000484800 / NM_182751.3; = p.P645S on NM_018518.5) | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MDGA1 | c.631dup p.S211Kfs*10 | Frame Shift Ins (INS) | VAF 49/227 reads (22%) | called by mutect2, pindel, varscan2
- MDGA2 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MED10 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- MED6 | c.706A>T p.K236* | Nonsense Mutation (SNP) | VAF 87/219 reads (40%) | called by muse, mutect2, varscan2
- MEMO1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MET | c.2896A>G p.S966G | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- METTL14 | c.448A>T p.R150W | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MEX3B | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MFSD14B | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MGAT4C | c.1219C>A p.H407N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MIA2 | c.1322del p.K441Rfs*17 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- MIER2 | c.898T>A p.C300S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MINDY4 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MKI67 | c.7145C>T p.S2382L | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MKRN3 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MMP16 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MMP2 | c.1325A>T p.Q442L | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MMP20 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MMP8 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC1 | c.1713T>A p.F571L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.3201G>C p.M1067I | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, varscan2
- MRC1 | c.4218del p.A1407Pfs*35 | Frame Shift Del (DEL) | VAF 267/884 reads (30%) | called by mutect2, pindel, varscan2
- MS4A4A | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- MS4A4A | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); called by muse, varscan2
786 further variants in this file (349 protein-altering or splice-affecting, 284 silent, 153 other) are not listed here.
